Somatic mutation profile of tumor specimen HCM-CSHL-0090-C25-86A (aliquot HCM-CSHL-0090-C25-86A-01D-A85C-36) from HCMI case HCM-CSHL-0090-C25, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: female; Vital status: Dead; Primary diagnosis: Infiltrating duct carcinoma, NOS; Tissue or organ of origin: Pancreas, NOS; AJCC pathologic stage: Stage III; Tumor grade: G3; Age at diagnosis: 64.8 years (23,666 days).
Specimen HCM-CSHL-0090-C25-86A: Sample type: Expanded Next Generation Cancer Model; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: 3D Organoid; Preservation method: Frozen; Passage count: 13.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) a3b2094f-c2f0-48a8-b7e6-0612409a962e.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen HCM-CSHL-0090-C25-10A (Blood Derived Normal), aliquot HCM-CSHL-0090-C25-10A-01D-A77E-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/c2ed2536-d87a-44ff-ab2c-f15c57197a4b

The open-access MAF lists 69 somatic variants for this specimen: 46 protein-altering or splice-affecting, 15 silent, 8 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 38, Silent 15, Intron 4, 5'UTR 3, Frame Shift Del 3, Nonsense Mutation 3, 3'Flank 1, In Frame Del 1, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.35G>A p.G12D | Missense Mutation (SNP) | VAF 244/356 reads (69%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen benign (0.303); catalogued as rs121913529, COSV55497369, COSV55497419, COSV55497479; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- SMAD4 | c.1324C>T p.Q442* | Nonsense Mutation (SNP) | VAF 181/181 reads (100%) | catalogued as rs1555687378, COSV61684132; ClinVar: pathogenic; called by muse, mutect2, varscan2
- CCDC173 | c.331C>T p.R111C | Missense Mutation (SNP) | VAF 22/360 reads (6%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.738); catalogued as rs774095741, COSV69573195; called by muse, mutect2
- CCDC180 | c.896G>A p.R299H | Missense Mutation (SNP) | VAF 119/423 reads (28%) | SIFT deleterious (0.02); PolyPhen benign (0.104); catalogued as rs377355984; called by muse, mutect2, varscan2
- CDH9 | c.290C>A p.A97D | Missense Mutation (SNP) | VAF 215/340 reads (63%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV50367579; called by muse, mutect2, varscan2
- CEACAM20 | c.1156C>T p.R386C | Missense Mutation (SNP) | VAF 151/658 reads (23%) | SIFT tolerated (0.13); PolyPhen benign (0.033); catalogued as rs181492260, COSV57601759; called by muse, mutect2, varscan2
- CELSR2 | c.7591G>A p.V2531I | Missense Mutation (SNP) | VAF 183/296 reads (62%) | SIFT tolerated (0.91); PolyPhen possibly damaging (0.47); catalogued as rs192472023; called by muse, mutect2, varscan2
- ESX1 | c.1040C>G p.P347R | Missense Mutation (SNP) | VAF 409/1107 reads (37%) | SIFT tolerated, low confidence (0.05); PolyPhen probably damaging (0.915); catalogued as rs200088361, COSV65423956; called by muse, mutect2
- ESYT1 | c.3151C>T p.Q1051* | Nonsense Mutation (SNP) | VAF 22/362 reads (6%) | catalogued as rs1471196585; called by muse, mutect2
- FAM155B | c.1115A>C p.K372T | Missense Mutation (SNP) | VAF 36/909 reads (4%) | SIFT tolerated (0.39); PolyPhen benign (0.067); catalogued as COSV52935094; called by muse, mutect2
- FLG | c.4615A>C p.S1539R | Missense Mutation (SNP) | VAF 28/574 reads (5%) | SIFT deleterious (0.01); PolyPhen benign (0.014); catalogued as rs536230632, COSV100912077, COSV64237938; called by muse, mutect2
- GRIK3 | c.244G>A p.D82N | Missense Mutation (SNP) | VAF 28/520 reads (5%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as COSV100901715; called by muse, mutect2
- GRIP1 | c.2429A>T p.D810V (on ENST00000359742 / NM_001379345.1; = p.D758V on NM_021150.4 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 250/375 reads (67%) | SIFT deleterious (0); PolyPhen possibly damaging (0.828); catalogued as rs1156346435; called by muse, mutect2, varscan2
- HINFP | c.356G>A p.R119Q | Missense Mutation (SNP) | VAF 271/454 reads (60%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.859); catalogued as rs963093960; called by muse, mutect2, varscan2
- KCNJ15 | c.85G>A p.V29I | Missense Mutation (SNP) | VAF 207/376 reads (55%) | SIFT tolerated (0.36); PolyPhen benign (0.047); catalogued as rs146159896; called by muse, mutect2, varscan2
- LPP | c.1558G>A p.G520R | Missense Mutation (SNP) | VAF 130/376 reads (35%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.895); catalogued as rs755218802, COSV100447890; called by muse, varscan2
- MARCHF8 | c.355G>A p.D119N | Missense Mutation (SNP) | VAF 350/659 reads (53%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.771); catalogued as rs75069175; called by muse, mutect2, varscan2
- NLRC3 | c.2800G>A p.G934R | Missense Mutation (SNP) | VAF 36/544 reads (7%) | SIFT deleterious (0.04); PolyPhen probably damaging (1); catalogued as rs1282597518; called by muse, mutect2
- NOTCH2 | c.4888C>A p.R1630S | Missense Mutation (SNP) | VAF 95/364 reads (26%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.933); catalogued as COSV56687234, COSV56701592; called by muse, mutect2, varscan2
- OR5H8 | c.687del p.V230Sfs*81 | Frame Shift Del (DEL) | VAF 66/254 reads (26%) | catalogued as rs553513516; called by mutect2, varscan2
- PDE1A | c.355C>T p.R119W | Missense Mutation (SNP) | VAF 141/373 reads (38%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); catalogued as rs770985972, COSV59515206; called by muse, mutect2, varscan2
- PDZRN3 | c.3154G>T p.D1052Y | Missense Mutation (SNP) | VAF 213/342 reads (62%) | SIFT deleterious (0); PolyPhen probably damaging (0.943); catalogued as COSV55200910; called by muse, mutect2, varscan2
- SLC12A5 | c.2045G>A p.R682H (on ENST00000454036 / NM_001134771.2; = p.R659H on NM_020708.5) | Missense Mutation (SNP) | VAF 256/429 reads (60%) | SIFT tolerated (0.07); PolyPhen benign (0.219); catalogued as rs1346179009; called by muse, mutect2, varscan2
- TMEM198 | c.856C>T p.R286W | Missense Mutation (SNP) | VAF 341/598 reads (57%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.672); catalogued as rs758782842; called by muse, mutect2, varscan2
- TNXB | c.4832C>T p.T1611M (on ENST00000647633; = p.T1364M on NM_019105.8 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 29/263 reads (11%) | SIFT deleterious (0.02); PolyPhen benign (0.23); catalogued as rs761085285; called by muse, mutect2, varscan2
- TP53 | c.414del p.K139Rfs*31 | Frame Shift Del (DEL) | VAF 361/505 reads (71%) | catalogued as rs137852794, COSV52677977; ClinVar: not provided; called by mutect2, pindel, varscan2
- WNK4 | c.1504G>A p.D502N | Missense Mutation (SNP) | VAF 115/442 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs759521316; called by muse, mutect2, varscan2
- ABCD3 | c.499C>A p.L167I | Missense Mutation (SNP) | VAF 104/183 reads (57%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.817); called by muse, mutect2, varscan2
- CDKN2A | c.259_276del p.R87_D92del | In Frame Del (DEL) | VAF 498/537 reads (93%) | called by mutect2, pindel, varscan2
- CHPF | c.1106G>T p.G369V | Missense Mutation (SNP) | VAF 18/534 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- CNBD2 | c.671A>T p.D224V | Missense Mutation (SNP) | VAF 269/465 reads (58%) | SIFT deleterious (0); PolyPhen possibly damaging (0.818); called by muse, mutect2, varscan2
- HCFC1 | c.4210G>A p.G1404S | Missense Mutation (SNP) | VAF 424/912 reads (46%) | SIFT tolerated, low confidence (0.29); PolyPhen benign (0); called by muse, mutect2, varscan2
- HDLBP | c.2305A>G p.K769E | Missense Mutation (SNP) | VAF 180/489 reads (37%) | SIFT tolerated (0.97); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- KANSL1 | c.1273C>T p.Q425* | Nonsense Mutation (SNP) | VAF 189/701 reads (27%) | called by muse, mutect2, varscan2
- KLF3 | c.673C>T p.P225S | Missense Mutation (SNP) | VAF 14/262 reads (5%) | SIFT tolerated (0.6); PolyPhen probably damaging (0.968); called by muse, mutect2
- KMT2D | c.11967del p.Q3989Hfs*33 | Frame Shift Del (DEL) | VAF 377/739 reads (51%) | called by mutect2, pindel, varscan2
- MAN2B2 | c.496G>A p.A166T | Missense Mutation (SNP) | VAF 70/481 reads (15%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.589); called by muse, mutect2, varscan2
- MAP1A | c.7966C>G p.P2656A | Missense Mutation (SNP) | VAF 46/742 reads (6%) | SIFT tolerated (0.26); PolyPhen benign (0.003); called by muse, mutect2
- MICU3 | c.489G>T p.M163I | Missense Mutation (SNP) | VAF 87/438 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.914); called by muse, mutect2, varscan2
- MUC16 | c.31535C>T p.S10512L | Missense Mutation (SNP) | VAF 112/427 reads (26%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- NR2C2 | c.673C>A p.P225T (on ENST00000393102; = p.P244T on NM_003298.5) | Missense Mutation (SNP) | VAF 23/486 reads (5%) | SIFT deleterious (0.04); PolyPhen benign (0.02); called by muse, mutect2
- NUP210 | c.3043C>G p.P1015A | Missense Mutation (SNP) | VAF 21/426 reads (5%) | SIFT tolerated (0.65); PolyPhen benign (0); called by muse, mutect2
- PKHD1L1 | c.9614A>T p.D3205V | Missense Mutation (SNP) | VAF 129/310 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.922); called by muse, mutect2, varscan2
- PLXNB3 | c.4688C>G p.T1563S | Missense Mutation (SNP) | VAF 402/766 reads (52%) | SIFT deleterious (0.01); PolyPhen benign (0.125); called by muse, mutect2, varscan2
- RGS6 | c.552dup p.D185Rfs*10 | Frame Shift Ins (INS) | VAF 41/157 reads (26%) | called by mutect2, pindel, varscan2
- TG | c.7294C>A p.Q2432K | Missense Mutation (SNP) | VAF 106/608 reads (17%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.939); called by muse, mutect2, varscan2
- BBS2 | c.1542C>T p.L514= | Silent (SNP) | VAF 80/300 reads (27%) | catalogued as rs374156464; called by muse, mutect2, varscan2
- COL6A3 | c.1209G>A p.P403= | Silent (SNP) | VAF 194/358 reads (54%) | catalogued as rs373903065; called by muse, mutect2, varscan2
- DOCK9 | c.927C>T p.S309= (on ENST00000376460 / NM_001366676.2; = p.S310= on NM_015296.3 and 1 other RefSeq transcript) | Silent (SNP) | VAF 236/341 reads (69%) | catalogued as rs755362899, COSV59645839; called by muse, mutect2, varscan2
- FBXO41 | c.2058G>A p.L686= | Silent (SNP) | VAF 83/316 reads (26%) | catalogued as COSV54590442; called by muse, mutect2, varscan2
- HOGA1 | c.216C>T p.F72= | Silent (SNP) | VAF 194/399 reads (49%) | catalogued as rs780606715, COSV65706601; ClinVar: likely benign; called by muse, mutect2, varscan2
- KLHL18 | c.1332C>T p.F444= | Silent (SNP) | VAF 169/270 reads (63%) | called by muse, mutect2, varscan2
- LRRC74B | c.9T>C p.G3= | Silent (SNP) | VAF 84/331 reads (25%) | called by muse, mutect2, varscan2
- MYT1L | c.1251G>A p.S417= | Silent (SNP) | VAF 39/576 reads (7%) | catalogued as rs774862534, COSV67727045; called by muse, mutect2
- PPP1R21 | c.516G>T p.L172= | Silent (SNP) | VAF 14/300 reads (5%) | called by muse, mutect2
- PSAP | c.501G>A p.V167= | Silent (SNP) | VAF 258/607 reads (43%) | called by muse, mutect2, varscan2
- RALA | c.72C>T p.G24= | Silent (SNP) | VAF 119/372 reads (32%) | catalogued as rs776867160, COSV50050565; called by muse, mutect2, varscan2
- SNX33 | c.1047G>A p.E349= | Silent (SNP) | VAF 24/724 reads (3%) | called by muse, mutect2
- ST8SIA6 | c.204A>G p.T68= | Silent (SNP) | VAF 119/259 reads (46%) | catalogued as rs751309814; called by muse, mutect2, varscan2
- TGFA | c.192G>T p.V64= | Silent (SNP) | VAF 168/301 reads (56%) | called by muse, mutect2, varscan2
- THUMPD2 | c.1137A>G p.K379= | Silent (SNP) | VAF 134/257 reads (52%) | catalogued as rs531948150; called by muse, mutect2, varscan2
- AC090151.1 | chr8:54701589 G>A | 3'Flank (SNP) | VAF 257/606 reads (42%) | catalogued as rs915217188; called by muse, mutect2, varscan2
- CNMD | c.-59G>A | 5'UTR (SNP) | VAF 39/181 reads (22%) | called by muse, mutect2, varscan2
- GLB1L3 | c.877-1959T>G | Intron (SNP) | VAF 26/422 reads (6%) | catalogued as COSV66283879; called by muse, mutect2
- GRN | c.138+34G>T | Intron (SNP) | VAF 176/375 reads (47%) | called by muse, mutect2, varscan2
- INPP5E | c.-2C>T | 5'UTR (SNP) | VAF 105/517 reads (20%) | catalogued as rs767541765; called by muse, mutect2, varscan2
- RGMA | c.15-634G>A | Intron (SNP) | VAF 28/341 reads (8%) | called by muse, mutect2
- SUCO | c.-206_-198del | 5'UTR (DEL) | VAF 203/645 reads (31%) | called by mutect2, pindel, varscan2
- TTN | c.34265-4497C>G | Intron (SNP) | VAF 147/521 reads (28%) | called by muse, mutect2, varscan2
